Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PU, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PU-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Bilateral thyroid nodules with papillary carcinoma of the right lobe.

Specimens Submitted:

- 1: Thyroid; total thyroidectomy
- 2: Pretracheal tissue; excision
- 3: Right paratracheal node; excision

DIAGNOSIS:

1. Thyroid; total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.8 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Four separate foci of papillary microcarcinoma in right and left lobes ranging from 0.1 to 0.8 cm.

ICD-0-3
carcinoma, papillary, thyroid, 8260/3
Site: thyroid, NOS C73.9
lw
8/31/11

[page 2 of 3]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Not identified

Lymph Nodes:
Two benign lymph nodes.

2. Pretracheal tissue; excision:

- Benign fibroadipose tissue.

3. Right paratracheal node; excision:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "total thyroidectomy" and consists of a thyroid weighing 20.5 g. The suture is in place by the surgeon to indicate the right lobe. The right lobe measures 4.5 x 3.5 x 2.5 cm, the left lobe measures 2.8 x 1.9 x 1.0 cm and the isthmus measures 2.5 x 0.5 x 0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a nodule in the right lobe that measures 2.8 x 2.5 x 2.2 cm. The nodule is partially solid and partially cystic. The solid area is fleshy and brown and has a calcified center. The left lobe contains a well-circumscribed, solid nodule that measures 1.0 x 0.6 x 0.6 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen have been submitted for TPS, and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted. A section with calcifications is decalcified prior processing.

Summary of sections:

RNC-- right thyroid lobe nodule with calcification

RL - right lobe

LL - left lobe

IS - isthmus

2) The specimen is received in formalin labeled "Pretracheal tissue" and consists of a 0.5 x 0.4 x 0.3 cm piece of fatty soft tissue. The specimen is entirely submitted.

Summary of sections:

U - undesignated

3) The specimen is received in formalin labeled "Right paratracheal nodes" and consists of a 1.1 x 1.1 x 0.3 cm piece of tan soft tissue. The specimen is entirely submitted.

Summary of sections:

LN - lymph nodes

[page 3 of 3]
Summary of Sections:**Part 1: Thyroid; total thyroidectomy**

Block	Sect. Site	PCs
4	LL	5
10	RL	12
1	RNC	2

Part 2: Pretracheal tissue; excision

Block	Sect. Site	PCs
1	U	1

Part 3: Right paratracheal node; excision

Block	Sect. Site	PCs
1	LN	1

Source: NCI Genomic Data Commons file 35fd212d-d735-4b7d-8593-a26d0043a1fe (TCGA-DJ-A2PU.AD5BA4BB-1EE5-4449-9942-79A097DE713A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).